Somatic mutation profile of tumor specimen TCGA-C5-A8ZZ-01A (aliquot TCGA-C5-A8ZZ-01A-11D-A37N-09) from TCGA case TCGA-C5-A8ZZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 41.8 years (15,262 days).
Specimen TCGA-C5-A8ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ab85c5-df7c-4859-a0f0-b55c28c32d4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8ZZ-10A (Blood Derived Normal), aliquot TCGA-C5-A8ZZ-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a098bf1e-ff4d-4181-b61f-8adf02a98e8e

The open-access MAF lists 91 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, 3'UTR 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3868G>A p.A1290T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143576497; called by mutect2, varscan2
- ACP3 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs370637506; called by muse, mutect2
- ACTRT1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs996690769, COSV64418926; called by mutect2, varscan2
- AK7 | c.2028G>C p.Q676H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV99967592; called by muse, mutect2, varscan2
- AKAP5 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1163854502, COSV100278096; called by muse, mutect2, varscan2
- ANLN | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202225666, COSV56080361, COSV99732962; called by muse, mutect2, varscan2
- ATF7IP | c.3327T>A p.N1109K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV99662206; called by muse, mutect2, varscan2
- ATP11B | c.2702T>C p.L901S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs760169325, COSV100018166; called by muse, mutect2, varscan2
- BACE1 | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100475370; called by muse, mutect2, varscan2
- BMP15 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782731311, COSV99399297, COSV99399555; called by muse, varscan2
- CAMSAP2 | c.1991G>A p.R664Q (on ENST00000236925 / NM_001297707.2; = p.R653Q on NM_203459.3) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs748956832, COSV99374459; called by muse, mutect2
- CCNB3 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1367595566, COSV99329989; called by muse, mutect2, varscan2
- CDAN1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as COSV99142565; called by muse, varscan2
- CLEC2D | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99325212; called by mutect2, varscan2
- CNDP1 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100722558; called by muse, mutect2, varscan2
- CNNM2 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100881946; called by muse, mutect2, varscan2
- CNTNAP3 | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as COSV99905752; called by muse, varscan2
- CSMD1 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV101226270; called by muse, mutect2, varscan2
- EPHA3 | c.1622A>G p.Q541R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100349291; called by muse, mutect2, varscan2
- FAM120A | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99466739; called by muse, mutect2, varscan2
- FAM47C | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1306926962, COSV100792980; called by muse, mutect2, varscan2
- FAM50B | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1288238703, COSV66654673; called by muse, mutect2, varscan2
- GPR45 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1285738675, COSV51523362; called by muse, mutect2, varscan2
- GRIPAP1 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100904404; called by muse, mutect2, varscan2
- H2AC15 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1260764326, COSV100357130; called by muse, mutect2, varscan2
- HTATSF1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs781072743, COSV54479778; called by muse, mutect2, varscan2
- HUWE1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV99474559; called by muse, mutect2, varscan2
- IKZF1 | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV100498815; called by muse, mutect2, varscan2
- IL27RA | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs746755376, COSV54599991; called by muse, mutect2, varscan2
- KCNJ16 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99388795; called by muse, mutect2, varscan2
- KMT2C | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs772146328; called by mutect2, varscan2
- LAMA1 | c.3569C>T p.T1190M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1473438503, COSV67532087; called by muse, mutect2
- LCT | c.4283G>A p.S1428N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99930592; called by muse, mutect2, varscan2
- MAP2 | c.1853A>T p.K618M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV99561938; called by muse, mutect2, varscan2
- MAP3K15 | c.2122A>G p.N708D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1324889063, COSV100135875; called by muse, mutect2, varscan2
- MORC4 | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99717677; called by muse, mutect2, varscan2
- MYO9B | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1244836942, COSV101262004; called by muse, mutect2
- OR51B5 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100332700; called by muse, mutect2, varscan2
- OR8B12 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs1291451040, COSV100172962; called by mutect2, varscan2
- PABPC4 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100790938; called by muse, mutect2, varscan2
- PCDHB12 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782525356, COSV53396558; called by muse, mutect2, varscan2
- PHEX | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416068968, COSV101040090; called by muse, varscan2
- PPP3CC | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99252504; called by muse, mutect2, varscan2
- PRICKLE3 | c.1241C>A p.T414K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV100889958; called by muse, mutect2, varscan2
- PRKAR1A | c.464C>G p.S155W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100675277; called by muse, mutect2, varscan2
- RALBP1 | c.956C>A p.S319Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50039640; called by muse, mutect2, varscan2
- RARG | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100553747; called by muse, varscan2
- RB1 | c.1688G>C p.W563S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM004729, CM040263, COSV57323482, COSV99927062; called by mutect2, varscan2
- RPA4 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100235625; called by muse, mutect2, varscan2
- SBF1 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100818078; called by muse, mutect2, varscan2
- SHROOM4 | c.4081G>C p.E1361Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99174839; called by muse, mutect2, varscan2
- SLC4A4 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52633784; called by muse, mutect2, varscan2
- SLC6A14 | c.1294A>C p.T432P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100903243; called by muse, mutect2, varscan2
- SP140 | c.1760C>G p.A587G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); catalogued as COSV100614140; called by muse, mutect2, varscan2
- SRSF3 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.267); catalogued as COSV100244982; called by muse, mutect2, varscan2
- SSH2 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99283221; called by muse, mutect2, varscan2
- SYAP1 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV101204978; called by muse, mutect2, varscan2
- SYNE2 | c.13921G>A p.E4641K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV100648568; called by muse, mutect2
- TMEM164 | c.745G>A p.G249S (on ENST00000372068 / NM_032227.4; = p.G100S on NM_017698.2) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55811666, COSV99912196; called by muse, mutect2, varscan2
- TOR1A | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs775770765, COSV61029206; called by muse, mutect2, varscan2
- UGT2A3 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV99280261; called by muse, mutect2, varscan2
- UNC13C | c.3965A>G p.E1322G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99523617; called by muse, mutect2, varscan2
- VAX1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547581837, COSV53329339; called by muse, mutect2, varscan2
- XYLT2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs758253451, COSV99191249; called by muse, mutect2
- ZC3H12B | c.2401A>G p.N801D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100162120; called by muse, mutect2, varscan2
- ZNF142 | c.2812G>A p.E938K (on ENST00000411696 / NM_001379660.1; = p.E738K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV101377012; called by muse, mutect2, varscan2
- LGALS12 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.342); called by muse, mutect2
- TPTE | c.535T>G p.F179V (on ENST00000618007 / NM_199261.4; = p.F161V on NM_199259.4) | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2
- USP12 | c.52_59del p.A18Ffs*16 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- ABI3 | c.360C>T p.P120= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs532695122, COSV56799461, COSV99865870; called by muse, mutect2, varscan2
- AKAP13 | c.7122C>A p.L2374= (on ENST00000394518 / NM_007200.5; = p.L2378= on NM_006738.6) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100774793; called by muse, mutect2, varscan2
- ARHGAP6 | c.2064G>A p.A688= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100273624; called by muse, mutect2, varscan2
- CACNA2D1 | c.1158G>A p.T386= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs753918568, COSV62393569; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP162 | c.2640A>G p.R880= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100003501; called by muse, mutect2, varscan2
- CLUAP1 | c.537C>T p.N179= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs780427055, COSV58895385; called by muse, mutect2, varscan2
- COL6A3 | c.6639C>T p.G2213= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs765837100, COSV55081842; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GALNT1 | c.1191G>T p.S397= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99322577; called by muse, mutect2, varscan2
- GFRA2 | c.981C>T p.G327= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs751473576, COSV100152132; called by muse, mutect2, varscan2
- IQGAP2 | c.957C>T p.P319= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs781281584, COSV99169248; called by muse, mutect2, varscan2
- ITPK1 | c.417T>C p.D139= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs751480924, COSV99969069; called by muse, mutect2
- OR2M2 | c.603C>T p.I201= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100677324; called by muse, mutect2, varscan2
- RNF220 | c.303C>T p.P101= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100699082, COSV62408815; called by muse, mutect2, varscan2
- SLC46A3 | c.1260G>A p.L420= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs754670282, COSV99906573; called by muse, mutect2, varscan2
- SRSF9 | c.177C>T p.F59= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99986749; called by muse, mutect2, varscan2
- TIAM2 | c.2400C>T p.D800= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs779194172, COSV59692273; called by muse, mutect2, varscan2
- TRIM42 | c.981C>A p.I327= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV99648222, COSV99648902; called by muse, mutect2, varscan2
- TRPM6 | c.6063A>G p.Q2021= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100667062; called by muse, mutect2
- YY2 | c.126C>T p.Y42= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV63412856; called by muse, mutect2
- ZNHIT2 | c.949C>T p.L317= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs754899615, COSV99659433; called by muse, mutect2, varscan2
- DACH2 | c.*1A>G | 3'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100914010; called by muse, mutect2, varscan2
- TAP2 | c.*37C>T | 3'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs754188775, COSV100886972; called by muse, mutect2, varscan2
